Somatic mutation profile of tumor specimen 0E1UJT from CCDI case PBCWSW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1UJT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee24952d-43d3-41c6-a73b-023ebc03e452.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1UIX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5072f1f-0ff1-4f0f-b56b-ce766616b185

The open-access MAF lists 12 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5428G>T p.D1810Y | Missense Mutation (SNP) | VAF 142/279 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58615443, COSV58615662, COSV58615890; called by mutect2, varscan2
- CTNNA2 | c.937G>A p.G313S | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63561718; called by muse, mutect2
- KCNN3 | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 77/509 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.462); catalogued as rs1409684244; called by muse, mutect2, varscan2
- VWA5B1 | c.1961G>A p.R654Q | Missense Mutation (SNP) | VAF 184/328 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs1390359139; called by muse, mutect2, varscan2
- PANK3 | c.790C>G p.P264A | Missense Mutation (SNP) | VAF 145/308 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- COL18A1 | c.4524C>T p.P1508= (on ENST00000359759 / NM_130444.3; = p.P1273= on NM_030582.4) | Silent (SNP) | VAF 127/261 reads (49%) | catalogued as rs529776494; called by muse, mutect2, varscan2
- PKP2 | c.2364C>T p.L788= | Silent (SNP) | VAF 176/394 reads (45%) | catalogued as rs765938307, COSV50740322; called by muse, mutect2, varscan2
- ZIM3 | c.1242C>T p.S414= | Silent (SNP) | VAF 164/310 reads (53%) | catalogued as rs372701407; called by muse, mutect2, varscan2
- ZNF460 | c.238C>T p.L80= | Silent (SNP) | VAF 112/317 reads (35%) | called by muse, mutect2, varscan2
- BOC | c.2887-68T>G | Intron (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- COL1A2 | c.3954+51del | Intron (DEL) | VAF 66/149 reads (44%) | catalogued as rs373778124; called by mutect2, pindel, varscan2
- PSMF1 | c.*1180C>G | 3'UTR (SNP) | VAF 146/232 reads (63%) | called by muse, mutect2, varscan2
